Somatic mutation profile of tumor specimen TCGA-17-Z049-01A (aliquot TCGA-17-Z049-01A-01W-0746-08) from TCGA case TCGA-17-Z049, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z049-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25e5d1ef-c0e7-43c7-b4b1-dc1db7d06ed3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z049-11A (Solid Tissue Normal), aliquot TCGA-17-Z049-11A-01W-0747-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eee02b4a-375e-4947-b2f1-b0f48f95423b

The open-access MAF lists 528 somatic variants for this specimen: 406 protein-altering or splice-affecting, 114 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 338, Silent 114, Nonsense Mutation 27, Splice Site 16, Frame Shift Del 14, Splice Region 5, Frame Shift Ins 4, RNA 4, 5'UTR 1, 3'UTR 1, 3'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A4 | c.657+1G>T p.X219_splice | Splice Site (SNP) | VAF 65/227 reads (29%) | catalogued as rs1553688696; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.380+1G>T p.X127_splice | Splice Site (SNP) | VAF 46/64 reads (72%) | hotspot (GDC flag); catalogued as CS0910368, CS982340, COSV57308473; called by muse, mutect2, varscan2
- TP53 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 202/237 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1064794311, CM973401, COSV52661102, COSV52687307, COSV99402633; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- A1CF | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 69/167 reads (41%) | catalogued as COSV50967889; called by muse, mutect2, varscan2
- ACSS3 | c.1121A>T p.D374V | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54096777; called by muse, mutect2, varscan2
- ACTG2 | c.274T>C p.Y92H | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.178); catalogued as rs1192497004; called by muse, mutect2, varscan2
- ADGRL4 | c.613G>C p.D205H | Missense Mutation (SNP) | VAF 76/178 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV66066097; called by muse, mutect2, varscan2
- ADGRV1 | c.15184del p.E5062Nfs*15 | Frame Shift Del (DEL) | VAF 16/41 reads (39%) | catalogued as COSV101316502; called by mutect2, pindel, varscan2
- AHNAK2 | c.5779G>T p.D1927Y | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs1490400300; called by muse, mutect2, varscan2
- AHNAK2 | c.5216G>T p.G1739V | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1340907996; called by muse, mutect2, varscan2
- AL136295.1 | c.1982G>T p.R661L | Missense Mutation (SNP) | VAF 126/253 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55778672; called by muse, varscan2
- AMOT | c.2240G>A p.R747K (on ENST00000371959 / NM_001113490.1; = p.R338K on NM_133265.3) | Missense Mutation (SNP) | VAF 208/229 reads (91%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100495127; called by mutect2, varscan2
- ANO2 | c.2288del p.P763Lfs*23 (on ENST00000356134 / NM_001278597.3; = p.P767Lfs*23 on NM_001278596.3) | Frame Shift Del (DEL) | VAF 34/50 reads (68%) | catalogued as COSV59014322; called by mutect2, pindel, varscan2
- ARAP3 | c.3677G>T p.R1226L | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs779573946, COSV99500178; called by muse, mutect2, varscan2
- ARHGEF2 | c.503G>T p.R168L (on ENST00000361247 / NM_001162383.2; = p.R141L on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.884); catalogued as COSV58105814; called by muse, mutect2, varscan2
- BANK1 | c.2236C>A p.P746T | Missense Mutation (SNP) | VAF 95/263 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV100536274; called by muse, mutect2, varscan2
- BICC1 | c.285G>T p.K95N | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99058287; called by muse, varscan2
- BIRC6 | c.8548G>A p.V2850I | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.096); catalogued as rs1346147364; called by muse, mutect2, varscan2
- C12orf40 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 166/181 reads (92%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.716); catalogued as COSV61132265; called by muse, mutect2, varscan2
- CBLN4 | c.606G>T p.*202Yext*6 | Nonstop Mutation (SNP) | VAF 138/252 reads (55%) | catalogued as COSV50352210, COSV50354341; called by mutect2, varscan2
- CCDC151 | c.419C>A p.P140Q | Missense Mutation (SNP) | VAF 120/289 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV52950819; called by muse, mutect2, varscan2
- CCDC59 | c.286C>T p.L96F | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781239166, COSV50258431; called by muse, mutect2, varscan2
- CD177 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 71/169 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as COSV65121473; called by muse, mutect2, varscan2
- CD1C | c.122G>C p.W41S | Missense Mutation (SNP) | VAF 117/251 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.277); catalogued as COSV63807867; called by muse, mutect2, varscan2
- CDH17 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 92/288 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs745532693, COSV50334391; called by muse, varscan2
- CDH22 | c.640G>T p.E214* | Nonsense Mutation (SNP) | VAF 33/59 reads (56%) | catalogued as rs755879706; called by muse, mutect2, varscan2
- CDH22 | c.160G>C p.A54P | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.35); PolyPhen benign (0.044); catalogued as rs763349285, COSV100952951; called by muse, mutect2, varscan2
- CDH23 | c.6584A>G p.N2195S | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.287); catalogued as rs1321272819; called by muse, mutect2, varscan2
- CEP112 | c.2414A>T p.Q805L (on ENST00000392769 / NM_001353127.1; = p.Q61L on NM_001037325.3) | Missense Mutation (SNP) | VAF 131/433 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV58064304; called by muse, mutect2, varscan2
- CLCA2 | c.318T>A p.Y106* | Nonsense Mutation (SNP) | VAF 31/64 reads (48%) | catalogued as rs780243230; called by muse, mutect2, varscan2
- CLIP2 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 172/508 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs150032298; called by muse, mutect2, varscan2
- COL19A1 | c.1447-1G>T p.X483_splice | Splice Site (SNP) | VAF 120/314 reads (38%) | catalogued as rs1350068271; called by muse, varscan2
- COL4A4 | c.4867C>A p.L1623M | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745928196; called by muse, mutect2, varscan2
- COL6A3 | c.6605G>A p.R2202Q | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs768050320, COSV55091677; called by muse, mutect2, varscan2
- COL6A6 | c.2735C>A p.P912H | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100650719; called by muse, mutect2, varscan2
- COPS2 | c.714A>G p.R238= | Splice Region (SNP) | VAF 22/58 reads (38%) | catalogued as COSV54645519; called by muse, mutect2, varscan2
- CRB1 | c.3106G>T p.E1036* | Nonsense Mutation (SNP) | VAF 71/173 reads (41%) | catalogued as COSV66328727, COSV66328731; called by muse, mutect2, varscan2
- CSMD1 | c.1226C>A p.A409E (on ENST00000520002; = p.A408E on NM_033225.6) | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs912861753; called by muse, mutect2, varscan2
- CYP27A1 | c.846del p.X282_splice | Splice Site (DEL) | VAF 23/60 reads (38%) | catalogued as CS016072, CS930788; called by mutect2, pindel, varscan2
- CYRIB | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 130/316 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.092); catalogued as COSV67828524; called by muse, mutect2, varscan2
- DCDC1 | c.3394C>A p.L1132I (on ENST00000597505 / NM_001367979.1; = p.L239I on NM_020869.3) | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.178); catalogued as COSV60305246, COSV60308419; called by muse, mutect2, varscan2
- DZIP3 | c.2944G>C p.V982L | Missense Mutation (SNP) | VAF 269/674 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.444); catalogued as rs148202329; called by muse, mutect2, varscan2
- ENPP2 | c.1780G>C p.E594Q (on ENST00000075322 / NM_001040092.3; = p.E646Q on NM_006209.5) | Missense Mutation (SNP) | VAF 363/864 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV99308500; called by muse, mutect2, varscan2
- EPHA3 | c.2771G>T p.W924L | Missense Mutation (SNP) | VAF 87/227 reads (38%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV60718525; called by muse, varscan2
- EVC | c.1075G>T p.D359Y | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV99381280; called by muse, mutect2, varscan2
- FAM114A1 | c.1536+2T>A p.X512_splice | Splice Site (SNP) | VAF 33/95 reads (35%) | catalogued as rs1286702184; called by muse, mutect2, varscan2
- FAM181B | c.1165C>T p.H389Y | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.101); catalogued as rs371988992; called by muse, mutect2
- FBN1 | c.5629C>T p.H1877Y | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as rs768076876; called by muse, mutect2, varscan2
- FCAR | c.508C>A p.Q170K | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.15); catalogued as COSV100629183; called by muse, mutect2, varscan2
- FZD5 | c.577C>G p.R193G | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV54943512; called by muse, mutect2, varscan2
- GIMAP8 | c.1471G>A p.V491I | Missense Mutation (SNP) | VAF 87/211 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV56233014; called by muse, mutect2, varscan2
- GLI3 | c.4625G>T p.R1542L | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV67892868; called by muse, mutect2, varscan2
- GMEB1 | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs763976493, COSV53793439, COSV53797344; called by muse, mutect2, varscan2
- GPC5 | c.765G>T p.M255I | Missense Mutation (SNP) | VAF 52/82 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100996396; called by muse, mutect2, varscan2
- GPR158 | c.1729C>T p.R577C | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs547187950, COSV66273277; called by muse, mutect2, varscan2
- H2BC10 | c.282G>T p.E94D | Missense Mutation (SNP) | VAF 72/155 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.157); catalogued as COSV59953830; called by muse, mutect2, varscan2
- HCRT | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as rs754595506, COSV52920362; called by muse, mutect2, varscan2
- HIF3A | c.1763G>T p.G588V (on ENST00000377670 / NM_152795.4; = p.G519V on NM_022462.4) | Missense Mutation (SNP) | VAF 94/181 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.619); catalogued as COSV52204742; called by muse, mutect2, varscan2
- HMGA2 | c.236G>C p.R79T | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV63591107; called by muse, varscan2
- HOXA5 | c.31G>T p.G11C | Missense Mutation (SNP) | VAF 96/197 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1395521067, COSV56072941; called by mutect2, varscan2
- HTR3C | c.1141G>T p.G381C | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV59174475; called by muse, mutect2, varscan2
- IFRD1 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 87/242 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.911); catalogued as rs1563266293; called by muse, mutect2, varscan2
- INPP4A | c.2846G>T p.R949L (on ENST00000074304 / NM_001134224.1; = p.R910L on NM_004027.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50794151, COSV50833962; called by muse, mutect2, varscan2
- IRF2BPL | c.1927G>C p.G643R | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as COSV53148071; called by muse, mutect2, varscan2
- JAK1 | c.1052A>G p.K351R | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99072543; called by muse, mutect2, varscan2
- KCNT2 | c.2466C>A p.N822K | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV54108310; called by muse, mutect2, varscan2
- KLHL26 | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56317739, COSV56318976; called by muse, mutect2, varscan2
- KPNA5 | c.823G>T p.V275L | Missense Mutation (SNP) | VAF 73/186 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV62651057; called by muse, mutect2, varscan2
- KRTAP19-7 | c.31C>A p.L11I | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.399); catalogued as rs1192725528; called by muse, mutect2
- LRIT1 | c.1190C>A p.S397Y | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as COSV64511926, COSV64513711; called by muse, mutect2, varscan2
- LRP2BP | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746701437; called by muse, mutect2, varscan2
- LZTR1 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 25/27 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763127267, COSV53146118; called by muse, mutect2, varscan2
- METTL1 | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 77/217 reads (35%) | catalogued as COSV55743625; called by muse, mutect2, varscan2
- MPZL1 | c.358A>G p.I120V | Missense Mutation (SNP) | VAF 110/246 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV63257402; called by muse, mutect2, varscan2
- MSR1 | c.1015G>A p.G339R | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV50517580; called by muse, mutect2, varscan2
- MTSS2 | c.1741G>A p.A581T | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs370854297; called by muse, mutect2, varscan2
- MUC17 | c.2165C>A p.S722* | Nonsense Mutation (SNP) | VAF 37/594 reads (6%) | catalogued as rs71530303, COSV60281985; called by muse, mutect2
- MVB12A | c.347A>T p.D116V | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100396553; called by muse, mutect2, varscan2
- NAALAD2 | c.781G>T p.G261C | Missense Mutation (SNP) | VAF 78/153 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58958361, COSV58963511; called by muse, mutect2, varscan2
- NAV3 | c.6472C>G p.Q2158E (on ENST00000397909 / NM_001024383.2; = p.Q2136E on NM_014903.6) | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57077157; called by muse, mutect2, varscan2
- NCK1 | c.350A>G p.Y117C | Missense Mutation (SNP) | VAF 153/367 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99999641; called by muse, mutect2, varscan2
- NDST4 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 126/365 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52124089, COSV99996753; called by muse, mutect2, varscan2
- NID1 | c.1607G>T p.R536L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.08); catalogued as COSV51628836, COSV99937633; called by muse, mutect2, varscan2
- NOVA2 | c.764C>A p.P255H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.216); catalogued as rs1301200097; called by muse, varscan2
- NR2F1 | c.403C>A p.R135S | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM154730; called by muse, mutect2, varscan2
- OR2C3 | c.529C>A p.H177N | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.989); catalogued as COSV63574331; called by muse, mutect2, varscan2
- OR4K17 | c.514A>T p.N172Y | Missense Mutation (SNP) | VAF 308/609 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59647966; called by muse, mutect2, varscan2
- OR56B1 | c.163del p.L55Sfs*24 | Frame Shift Del (DEL) | VAF 75/125 reads (60%) | catalogued as COSV100402705; called by mutect2, pindel, varscan2
- OR5D18 | c.812C>A p.T271K | Missense Mutation (SNP) | VAF 88/231 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.392); catalogued as COSV61736614; called by muse, mutect2, varscan2
- OR5H6 | c.341T>C p.M114T (on ENST00000642105; = p.M98T on NM_001005479.2) | Missense Mutation (SNP) | VAF 84/201 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs756306873; called by muse, mutect2, varscan2
- OSBPL10 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.978); catalogued as rs763437591; called by muse, mutect2, varscan2
- PARD3B | c.1607G>T p.G536V | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762996571; called by muse, mutect2, varscan2
- PARN | c.832G>T p.A278S | Missense Mutation (SNP) | VAF 82/104 reads (79%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs772291762; called by muse, mutect2, varscan2
- PCDHA1 | c.1717A>C p.T573P | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs782387840; called by muse, mutect2, varscan2
- PCDHB1 | c.1936C>G p.Q646E | Missense Mutation (SNP) | VAF 70/180 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs557385506, COSV99080137; called by muse, mutect2, varscan2
- PCDHB10 | c.389C>A p.A130E | Missense Mutation (SNP) | VAF 68/209 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.069); catalogued as rs1333580766, COSV53376430; called by muse, mutect2, varscan2
- PCDHGB7 | c.795G>T p.K265N | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.158); catalogued as COSV53915743; called by muse, mutect2, varscan2
- PDCD1 | c.327C>A p.S109R | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.882); catalogued as COSV57690587; called by muse, mutect2, varscan2
- PDE3B | c.236G>C p.R79P | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated (0.26); PolyPhen benign (0.333); catalogued as COSV56387579; called by muse, mutect2, varscan2
- PLBD2 | c.1388G>T p.R463L | Missense Mutation (SNP) | VAF 94/218 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.041); catalogued as COSV55109399, COSV99785275; called by muse, mutect2, varscan2
- PRDM9 | c.2564C>A p.T855K | Missense Mutation (SNP) | VAF 95/282 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV57002668; called by mutect2, varscan2
- PRKCE | c.822A>T p.K274N | Missense Mutation (SNP) | VAF 151/413 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as COSV100076660; called by muse, varscan2
- PTPRC | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100722265; called by muse, mutect2, varscan2
- PTPRD | c.823G>T p.D275Y | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61939843; called by muse, mutect2, varscan2
- PYGL | c.1679C>G p.P560R | Missense Mutation (SNP) | VAF 180/325 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV53588738; called by muse, mutect2, varscan2
- QRFPR | c.962G>T p.G321V | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57676107; called by muse, mutect2, varscan2
- RAPGEF4 | c.2380-1G>T p.X794_splice | Splice Site (SNP) | VAF 52/108 reads (48%) | catalogued as COSV51388592; called by muse, mutect2, varscan2
- RYR1 | c.12028G>T p.E4010* | Nonsense Mutation (SNP) | VAF 34/89 reads (38%) | catalogued as CM152884, COSV100615442, COSV62090314, COSV62107399; called by muse, varscan2
- SCNN1G | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs955520279, COSV100264035, COSV55597342; called by muse, mutect2, varscan2
- SETX | c.5936G>T p.R1979L | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV99810045; called by muse, mutect2, varscan2
- SIGLEC10 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 148/269 reads (55%) | SIFT tolerated (0.71); PolyPhen benign (0.033); catalogued as rs370133178; called by muse, mutect2, varscan2
- SIGLEC9 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 156/313 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV51582568, COSV51582801, COSV51586246; called by muse, mutect2, varscan2
- SOAT1 | c.1568A>G p.Y523C | Missense Mutation (SNP) | VAF 240/570 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1463340717; called by muse, mutect2, varscan2
- SPATA31A3 | c.368del p.P123Qfs*30 | Frame Shift Del (DEL) | VAF 63/382 reads (16%) | catalogued as rs1244414423; called by mutect2, pindel, varscan2
- TAS2R19 | c.56T>C p.L19P | Missense Mutation (SNP) | VAF 92/110 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs772769325; called by muse, mutect2, varscan2
- TDRD6 | c.6160G>T p.E2054* | Nonsense Mutation (SNP) | VAF 67/442 reads (15%) | catalogued as rs754359392, COSV60175189; called by muse, mutect2, varscan2
- TLN2 | c.1375G>T p.G459C | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV60885609; called by muse, mutect2, varscan2
- TMCC1 | c.1393G>T p.E465* (on ENST00000393238 / NM_001349268.2; = p.E141* on NM_015008.5 and 6 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 84/173 reads (49%) | catalogued as COSV100260843; called by muse, mutect2, varscan2
- TMEM131 | c.4850G>T p.R1617L | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV51787920, COSV99488244; called by muse, mutect2, varscan2
- TMEM30A | c.890A>G p.Y297C | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV100035004; called by muse, mutect2, varscan2
- TNNT2 | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 167/451 reads (37%) | catalogued as CM063211, COSV52662217, COSV52663283; called by muse, mutect2
- TRAF3 | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs767055689, COSV61024005; called by muse, mutect2, varscan2
- TSHZ2 | c.2706C>A p.N902K | Missense Mutation (SNP) | VAF 93/149 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748554234, COSV100296911; called by muse, mutect2, varscan2
- TUT4 | c.3232-1G>T p.X1078_splice | Splice Site (SNP) | VAF 37/95 reads (39%) | catalogued as COSV99932998; called by muse, mutect2, varscan2
- UGT1A1 | c.1046C>A p.T349K | Missense Mutation (SNP) | VAF 49/222 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776227074, COSV59392819; called by muse, mutect2, varscan2
- UGT1A10 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 116/227 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.258); catalogued as rs145610800; called by muse, mutect2, varscan2
- UNC93A | c.1277G>T p.G426V | Missense Mutation (SNP) | VAF 158/457 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.441); catalogued as COSV57809950; called by muse, mutect2, varscan2
- USP36 | c.2176C>T p.H726Y | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs760114925; called by muse, mutect2, varscan2
- VPS37D | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.91); catalogued as rs1255482461; called by muse, mutect2, varscan2
- WDR70 | c.175+1G>T p.X59_splice | Splice Site (SNP) | VAF 66/134 reads (49%) | catalogued as COSV99459733; called by muse, mutect2, varscan2
- ZIC1 | c.501C>A p.F167L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (1); PolyPhen probably damaging (0.983); catalogued as COSV51557205; called by muse, mutect2, varscan2
- ZNF7 | c.1835A>G p.Y612C | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs768190813; called by muse, varscan2
- ZNF804A | c.2410G>T p.A804S | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.162); catalogued as COSV56437680; called by muse, mutect2, varscan2
- ZW10 | c.2219G>C p.R740P | Missense Mutation (SNP) | VAF 166/554 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV52314839, COSV52319566; called by muse, varscan2
- ZW10 | c.2218C>T p.R740W | Missense Mutation (SNP) | VAF 172/564 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs775877234, COSV52319580; called by muse, varscan2
- ZZEF1 | c.289C>G p.L97V | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as COSV56801352; called by muse, mutect2, varscan2
- ABCA13 | c.10819G>T p.G3607* | Nonsense Mutation (SNP) | VAF 85/208 reads (41%) | called by muse, varscan2
- ABCA4 | c.5273A>C p.E1758A | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.94); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCC9 | c.1002C>A p.N334K | Missense Mutation (SNP) | VAF 67/78 reads (86%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC004593.2 | c.869A>G p.H290R | Missense Mutation (SNP) | VAF 141/354 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- ACTL7B | c.1098C>A p.D366E | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AHCYL2 | c.1676A>T p.K559M | Missense Mutation (SNP) | VAF 150/333 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- AHR | c.1082_1115del p.T361Kfs*10 | Frame Shift Del (DEL) | VAF 36/82 reads (44%) | called by mutect2, pindel
- ANGPTL8 | c.80C>A p.P27Q | Missense Mutation (SNP) | VAF 74/124 reads (60%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK2 | c.11413G>C p.A3805P | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK3 | c.11516G>T p.C3839F | Missense Mutation (SNP) | VAF 229/612 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKLE2 | c.1903A>G p.I635V | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ANKRD24 | c.984G>T p.R328S | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- ARHGAP27 | c.1478G>T p.R493M (on ENST00000428638 / NM_001282290.1; = p.R152M on NM_199282.3) | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- ARMC9 | c.127T>A p.C43S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BAIAP3 | c.1707+1G>A p.X569_splice | Splice Site (SNP) | VAF 20/29 reads (69%) | called by muse, mutect2, varscan2
- BCO1 | c.1508C>G p.A503G | Missense Mutation (SNP) | VAF 84/107 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BTBD11 | c.1290C>A p.D430E | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- C16orf82 | c.354G>T p.Q118H | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.05); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- CACNA1B | c.5761A>T p.S1921C | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CACNA1D | c.3911C>T p.P1304L (on ENST00000350061 / NM_001128840.3; = p.P1324L on NM_000720.4) | Missense Mutation (SNP) | VAF 102/282 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CACNA1E | c.1777G>A p.V593M | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CACNA2D1 | c.2068A>G p.K690E (on ENST00000356253 / NM_001366867.1; = p.K678E on NM_000722.4) | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.95); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNA2D3 | c.710T>C p.I237T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- CALCOCO1 | c.1958G>T p.W653L | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CALCRL | c.137A>T p.Y46F | Missense Mutation (SNP) | VAF 97/222 reads (44%) | SIFT tolerated (0.88); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CALR3 | c.812A>T p.H271L | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CC2D2A | c.4220A>C p.Y1407S | Missense Mutation (SNP) | VAF 146/271 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC151 | c.418C>G p.P140A | Missense Mutation (SNP) | VAF 120/287 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- CCIN | c.1545_1546del p.S516Pfs*? | Frame Shift Del (DEL) | VAF 80/208 reads (38%) | called by pindel, varscan2
- CCN3 | c.309G>T p.T103= | Splice Region (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- CCNO | c.917G>C p.G306A | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- CDC20B | c.1174G>T p.G392C | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDH23 | c.6125T>A p.L2042Q | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- CDHR3 | c.1396T>A p.Y466N | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CELA3B | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CES5A | c.208del p.L70Cfs*34 | Frame Shift Del (DEL) | VAF 24/46 reads (52%) | called by mutect2, pindel, varscan2
- CFAP43 | c.2621A>T p.K874M | Missense Mutation (SNP) | VAF 248/496 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- CFAP65 | c.3109G>A p.A1037T | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT tolerated (0.47); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CHL1 | c.1759G>A p.G587S (on ENST00000397491 / NM_001253387.1; = p.G603S on NM_006614.4) | Missense Mutation (SNP) | VAF 100/244 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHML | c.810A>T p.E270D | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CHML | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 156/446 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.033); called by muse, varscan2
- CHSY3 | c.2323T>C p.W775R | Missense Mutation (SNP) | VAF 109/263 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CNTNAP3 | c.2092C>A p.L698M | Missense Mutation (SNP) | VAF 78/212 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- CNTNAP5 | c.3820A>T p.M1274L | Missense Mutation (SNP) | VAF 124/396 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL11A1 | c.654G>T p.G218= | Splice Region (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- COL11A1 | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COLGALT1 | c.1450G>T p.V484L | Missense Mutation (SNP) | VAF 105/202 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- COMMD1 | c.361G>T p.G121C | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, varscan2
- CRELD1 | c.425G>A p.C142Y | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD2 | c.1582G>C p.A528P | Missense Mutation (SNP) | VAF 5/144 reads (3%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.93); called by muse, mutect2
- CSRP3 | c.202C>A p.P68T | Missense Mutation (SNP) | VAF 237/280 reads (85%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by mutect2, varscan2
- CTNNA1 | c.1573A>T p.K525* | Nonsense Mutation (SNP) | VAF 64/182 reads (35%) | called by muse, mutect2, varscan2
- CUBN | c.3883G>C p.G1295R | Missense Mutation (SNP) | VAF 99/260 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- CYP7B1 | c.474G>C p.M158I | Missense Mutation (SNP) | VAF 66/125 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- DCD | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- DENND5A | c.976G>C p.E326Q | Missense Mutation (SNP) | VAF 68/85 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DIO2 | c.625del p.R209Efs*? | Frame Shift Del (DEL) | VAF 51/134 reads (38%) | called by mutect2, varscan2
- DLAT | c.1463G>T p.C488F | Missense Mutation (SNP) | VAF 87/154 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DMBT1 | c.6036G>C p.L2012F (on ENST00000338354 / NM_001377530.1; = p.L1255F on NM_004406.3) | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- DNAJC5B | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- DPYD | c.740T>G p.L247R | Missense Mutation (SNP) | VAF 69/163 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- EIF2AK1 | c.1417A>G p.N473D | Missense Mutation (SNP) | VAF 41/313 reads (13%) | SIFT tolerated (0.92); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EMILIN3 | c.489C>A p.Y163* | Nonsense Mutation (SNP) | VAF 39/120 reads (33%) | called by muse, mutect2, varscan2
- ERBB2 | c.1951C>G p.L651V | Missense Mutation (SNP) | VAF 177/336 reads (53%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- EZHIP | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FAIM2 | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- FAM120B | c.357C>G p.I119M | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- FAM83C | c.1622C>T p.P541L | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBXO47 | c.676C>A p.H226N | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- FETUB | c.284T>C p.V95A | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FEZ1 | c.657G>T p.W219C | Missense Mutation (SNP) | VAF 78/156 reads (50%) | SIFT tolerated (0.93); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FGD5 | c.2820G>C p.E940D | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FHL5 | c.504+1G>T p.X168_splice | Splice Site (SNP) | VAF 40/105 reads (38%) | called by muse, mutect2, varscan2
- FLI1 | c.896G>T p.C299F | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- FLI1 | c.1030G>T p.D344Y | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FSHR | c.1578G>C p.L526F | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- FSTL5 | c.964T>A p.Y322N | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- FSTL5 | c.963C>A p.C321* | Nonsense Mutation (SNP) | VAF 30/97 reads (31%) | called by muse, mutect2, varscan2
- FUT3 | c.4G>C p.D2H | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- GLDC | c.862-2A>G p.X288_splice | Splice Site (SNP) | VAF 84/198 reads (42%) | called by muse, varscan2
- GPM6A | c.827C>A p.A276E | Missense Mutation (SNP) | VAF 82/227 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GPR158 | c.3306G>T p.E1102D | Missense Mutation (SNP) | VAF 79/202 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- GPX7 | c.304A>T p.S102C | Missense Mutation (SNP) | VAF 109/281 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- HECTD1 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- HEPHL1 | c.1857C>A p.N619K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- HGF | c.120dup p.E41* | Frame Shift Ins (INS) | VAF 30/89 reads (34%) | called by mutect2, varscan2
- HNRNPA0 | c.497A>T p.H166L | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- HNRNPUL2 | c.1909G>T p.E637* | Nonsense Mutation (SNP) | VAF 40/115 reads (35%) | called by mutect2, varscan2
- HSD17B4 | c.2280G>T p.K760N (on ENST00000414835 / NM_001199291.3; = p.K735N on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- IL17RD | c.301G>T p.G101W | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- IRAK2 | c.299G>T p.R100M | Missense Mutation (SNP) | VAF 152/365 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.076); called by muse, varscan2
- ITPR3 | c.5192A>C p.E1731A | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- IVL | c.1403A>T p.K468M | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- KALRN | c.4826G>T p.R1609M | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KCNN3 | c.2149G>T p.V717L (on ENST00000618040 / NM_001204087.1; = p.V702L on NM_002249.6) | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KCTD3 | c.1960C>T p.P654S | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIAA1586 | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KIF3A | c.422C>A p.T141K | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KLC2 | c.769A>T p.K257* | Nonsense Mutation (SNP) | VAF 98/230 reads (43%) | called by muse, mutect2, varscan2
- KRT85 | c.440A>T p.Q147L | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- KRTAP12-2 | c.71G>C p.C24S | Missense Mutation (SNP) | VAF 48/89 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- KRTAP4-3 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, varscan2
- LAMA2 | c.6511G>T p.V2171F | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- LAMA5 | c.2387A>T p.Q796L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- LCP2 | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- LGALS9C | c.449C>A p.P150H | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LHCGR | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.007); called by muse, mutect2
- LIG1 | c.1057G>T p.V353F | Missense Mutation (SNP) | VAF 81/158 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- LRIG2 | c.2773G>T p.A925S | Missense Mutation (SNP) | VAF 76/190 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP2 | c.6479A>G p.Y2160C | Missense Mutation (SNP) | VAF 57/104 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRP2 | c.3763G>T p.D1255Y | Missense Mutation (SNP) | VAF 142/268 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRK1 | c.4970T>C p.V1657A | Missense Mutation (SNP) | VAF 78/222 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- LYST | c.11066G>T p.W3689L | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGEB18 | c.962G>T p.R321M | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- MAGEL2 | c.2522A>T p.N841I | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- MAP3K3 | c.1286G>T p.G429V | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MATN2 | c.408dup p.G137Wfs*47 | Frame Shift Ins (INS) | VAF 27/72 reads (38%) | called by mutect2, pindel, varscan2
- MDH1 | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- MEGF10 | c.2267C>A p.A756E | Missense Mutation (SNP) | VAF 116/250 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- MICAL1 | c.1816C>A p.H606N | Missense Mutation (SNP) | VAF 72/140 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- MKRN3 | c.373A>G p.K125E | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- MLLT10 | c.1595G>T p.S532I | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MRE11 | c.1739G>A p.R580K | Missense Mutation (SNP) | VAF 282/775 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MRPL9 | c.765del p.A256Lfs*62 | Frame Shift Del (DEL) | VAF 48/148 reads (32%) | called by pindel, varscan2
- MUC16 | c.6226G>T p.G2076C | Missense Mutation (SNP) | VAF 311/777 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MUC17 | c.13298G>A p.W4433* | Nonsense Mutation (SNP) | VAF 76/157 reads (48%) | called by muse, mutect2, varscan2
- MYCBP2 | c.5537G>A p.R1846K (on ENST00000357337; = p.R1884K on NM_015057.5) | Missense Mutation (SNP) | VAF 99/308 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); called by muse, varscan2
- MYH10 | c.4707G>T p.M1569I | Missense Mutation (SNP) | VAF 154/342 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- MYOM2 | c.207G>T p.R69S | Missense Mutation (SNP) | VAF 71/147 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NCAM2 | c.417C>A p.S139R | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- NCAN | c.3119G>T p.G1040V | Missense Mutation (SNP) | VAF 79/221 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NDE1 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 30/34 reads (88%) | SIFT tolerated (0.2); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- NDRG4 | c.1022T>A p.L341Q (on ENST00000570248 / NM_001378344.1; = p.L360Q on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT tolerated (0.6); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- NDUFS4 | c.190T>G p.L64V | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NEO1 | c.1132G>T p.G378W | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NFASC | c.3719C>A p.A1240D (on ENST00000339876 / NM_001378329.1; = p.A1169D on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- NFATC4 | c.1657G>T p.V553L | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NLRP13 | c.1188G>T p.M396I | Missense Mutation (SNP) | VAF 129/236 reads (55%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP13 | c.1069G>C p.A357P | Missense Mutation (SNP) | VAF 87/245 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOL6 | c.3367C>G p.L1123V | Missense Mutation (SNP) | VAF 67/138 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- OASL | c.523G>T p.V175L | Missense Mutation (SNP) | VAF 114/214 reads (53%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- OR10A6 | c.605del p.G202Afs*4 | Frame Shift Del (DEL) | VAF 89/137 reads (65%) | called by mutect2, pindel, varscan2
- OR14C36 | c.486C>A p.F162L | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2B11 | c.212C>A p.S71Y | Missense Mutation (SNP) | VAF 187/448 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- OR3A1 | c.390C>A p.C130* | Nonsense Mutation (SNP) | VAF 171/198 reads (86%) | called by muse, mutect2, varscan2
- OR5B2 | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 47/442 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.678); called by muse, varscan2
- OVOL1 | c.258C>A p.D86E | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.83); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PCARE | c.2144C>A p.A715D | Missense Mutation (SNP) | VAF 85/157 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- PDE1A | c.316G>T p.G106W | Missense Mutation (SNP) | VAF 123/378 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- PDE3B | c.2516del p.P839Lfs*47 | Frame Shift Del (DEL) | VAF 114/189 reads (60%) | called by mutect2, pindel, varscan2
- PDE6A | c.1063C>A p.L355M | Missense Mutation (SNP) | VAF 203/469 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- PDZRN3 | c.2189A>G p.N730S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- PEG3 | c.1175G>A p.R392K | Missense Mutation (SNP) | VAF 159/445 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- PHOX2A | c.272G>C p.R91P | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PID1 | c.226C>G p.L76V (on ENST00000354069 / NM_001330156.1; = p.L74V on NM_017933.5) | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PKHD1 | c.9189C>A p.N3063K | Missense Mutation (SNP) | VAF 118/272 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PKN3 | c.970G>T p.G324C | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- PLEKHA7 | c.1648G>T p.D550Y | Missense Mutation (SNP) | VAF 65/77 reads (84%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- PML | c.2562G>C p.L854F | Missense Mutation (SNP) | VAF 71/173 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- PNLIPRP2 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNLIPRP3 | c.1285C>A p.Q429K | Missense Mutation (SNP) | VAF 170/378 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- POLG | c.1324G>T p.E442* | Nonsense Mutation (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- POM121L12 | c.224C>A p.T75N | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPM1D | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- PRAMEF15 | c.569dup p.L190Ffs*116 | Frame Shift Ins (INS) | VAF 136/693 reads (20%) | called by mutect2, pindel, varscan2
- PRPF39 | c.427G>C p.D143H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- PRRC2B | c.1417G>T p.G473C | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- PRSS48 | c.983G>A p.R328K | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, varscan2
- PSD3 | c.2557G>T p.A853S (on ENST00000440756; = p.A852S on NM_015310.4) | Missense Mutation (SNP) | VAF 164/363 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PXDN | c.2460G>T p.Q820H | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- R3HDML | c.536G>T p.R179L | Missense Mutation (SNP) | VAF 130/393 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- RAB3GAP2 | c.3249G>T p.R1083S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RAB5C | c.532A>C p.I178L | Missense Mutation (SNP) | VAF 155/412 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- RAPGEF6 | c.351+1G>T p.X117_splice | Splice Site (SNP) | VAF 59/182 reads (32%) | called by muse, mutect2, varscan2
- RBM12 | c.2489G>T p.G830V | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- RBP2 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 139/328 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- RELN | c.1442-1G>C p.X481_splice | Splice Site (SNP) | VAF 102/240 reads (43%) | called by muse, mutect2, varscan2
- RFX6 | c.1820C>A p.P607H | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- RHEX | c.460T>C p.W154R | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF17 | c.1556A>T p.D519V | Missense Mutation (SNP) | VAF 58/73 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RTTN | c.3341G>C p.G1114A | Missense Mutation (SNP) | VAF 88/158 reads (56%) | SIFT tolerated (0.49); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RYR2 | c.1859G>T p.C620F | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- RYR2 | c.2914C>G p.L972V | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RYR3 | c.965C>A p.A322E | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- RYR3 | c.8315C>T p.T2772I (on ENST00000389232; = p.T2773I on NM_001036.6) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SAMD9L | c.2353del p.V785Sfs*38 | Frame Shift Del (DEL) | VAF 245/836 reads (29%) | called by mutect2, pindel, varscan2
- SARDH | c.1433T>C p.L478P | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SCARA5 | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 137/332 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SCN3A | c.4630A>T p.M1544L | Missense Mutation (SNP) | VAF 60/110 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SELE | c.1027G>T p.G343* | Nonsense Mutation (SNP) | VAF 70/118 reads (59%) | called by muse, mutect2, varscan2
- SELE | c.846G>C p.Q282H | Missense Mutation (SNP) | VAF 51/190 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- SEMA5A | c.2039G>T p.C680F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SEMA5B | c.152C>A p.A51D | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- SERPINA10 | c.407C>A p.T136N | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- SETD2 | c.6953C>T p.P2318L | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SF3B4 | c.896G>A p.G299D | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SGCD | c.722G>T p.R241M (on ENST00000435422 / NM_001128209.2; = p.R242M on NM_000337.5) | Missense Mutation (SNP) | VAF 75/193 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- SH2D4B | c.1210G>C p.E404Q (on ENST00000646907; = p.G329A on NM_207372.2) | Missense Mutation (SNP) | VAF 89/195 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- SHROOM4 | c.3031G>T p.D1011Y | Missense Mutation (SNP) | VAF 63/68 reads (93%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- SI | c.982G>T p.G328* | Nonsense Mutation (SNP) | VAF 30/91 reads (33%) | called by muse, mutect2, varscan2
- SLC12A1 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 29/84 reads (35%) | called by muse, varscan2
- SLC25A23 | c.671A>G p.N224S | Missense Mutation (SNP) | VAF 71/161 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SLC25A41 | c.423G>C p.Q141H | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SLC26A8 | c.2003T>C p.V668A | Missense Mutation (SNP) | VAF 168/459 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SLC27A6 | c.1714C>G p.L572V | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- SLC4A3 | c.3125G>T p.G1042V | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC9C2 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- SLCO2A1 | c.416A>T p.Q139L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- SNRPG | c.184A>G p.I62V | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SNX1 | c.1059G>T p.M353I | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- SNX2 | c.1431A>T p.R477S | Missense Mutation (SNP) | VAF 62/159 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- SORD | c.786+1G>T p.X262_splice | Splice Site (SNP) | VAF 16/71 reads (23%) | called by muse, mutect2, varscan2
- SOX13 | c.84G>T p.E28D | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SPATA5 | c.1259del p.G420Vfs*5 | Frame Shift Del (DEL) | VAF 90/229 reads (39%) | called by mutect2, varscan2
- SPEG | c.4816G>T p.E1606* | Nonsense Mutation (SNP) | VAF 44/70 reads (63%) | called by muse, mutect2, varscan2
- SPTBN1 | c.605G>T p.W202L | Missense Mutation (SNP) | VAF 59/98 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SSU72P8 | c.185A>T p.K62M | Missense Mutation (SNP) | VAF 188/380 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- ST7 | c.1180G>T p.G394W (on ENST00000265437 / NM_021908.3; = p.G371W on NM_018412.4) | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STK10 | c.1907G>T p.R636L | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SULF1 | c.1422C>G p.H474Q | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SYMPK | c.1086G>T p.L362= | Splice Region (SNP) | VAF 138/282 reads (49%) | called by muse, varscan2
- TACC2 | c.4975G>T p.E1659* | Nonsense Mutation (SNP) | VAF 34/79 reads (43%) | called by muse, mutect2, varscan2
- TAOK3 | c.2039A>T p.Q680L | Missense Mutation (SNP) | VAF 82/252 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- TAP2 | c.542del p.G181Efs*69 | Frame Shift Del (DEL) | VAF 40/138 reads (29%) | called by mutect2, pindel, varscan2
- TAS2R41 | c.217A>G p.K73E | Missense Mutation (SNP) | VAF 83/331 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TASOR | c.1400A>T p.Y467F (on ENST00000355628 / NM_001365636.2; = p.Y71F on NM_015224.3) | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TBX2 | c.526G>T p.G176C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- TDRD3 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 118/302 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- TDRD7 | c.2326C>G p.L776V | Missense Mutation (SNP) | VAF 195/516 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TENM2 | c.8272G>T p.D2758Y (on ENST00000518659 / NM_001122679.2; = p.D2519Y on NM_001080428.3) | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENM4 | c.5818C>G p.Q1940E | Missense Mutation (SNP) | VAF 82/168 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- TF | c.1549T>A p.C517S | Missense Mutation (SNP) | VAF 65/175 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TG | c.2659A>G p.S887G | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- TGFB2 | c.637C>A p.H213N | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TLN2 | c.524G>A p.W175* | Nonsense Mutation (SNP) | VAF 24/85 reads (28%) | called by muse, mutect2, varscan2
- TLN2 | c.525G>T p.W175C | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TLR6 | c.2023G>T p.E675* | Nonsense Mutation (SNP) | VAF 111/230 reads (48%) | called by muse, mutect2, varscan2
- TMEM131L | c.1665C>T p.C555= | Splice Region (SNP) | VAF 33/100 reads (33%) | called by muse, mutect2, varscan2
- TMEM132D | c.1846G>T p.V616L | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.698); called by muse, mutect2
- TMEM132D | c.883A>G p.I295V | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMOD1 | c.356C>A p.A119D | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TNFSF8 | c.536C>A p.S179Y | Missense Mutation (SNP) | VAF 88/330 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by mutect2, varscan2
- TNS3 | c.872A>T p.Y291F | Missense Mutation (SNP) | VAF 80/180 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TPTE | c.890A>T p.N297I (on ENST00000618007 / NM_199261.4; = p.N279I on NM_199259.4) | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- TRPC3 | c.2221G>T p.A741S (on ENST00000379645 / NM_001366479.2; = p.A668S on NM_003305.2) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSHZ1 | c.1889dup p.P631Tfs*30 (on ENST00000580243 / NM_001308210.2; = p.P586Tfs*30 on NM_005786.6) | Frame Shift Ins (INS) | VAF 31/89 reads (35%) | called by mutect2, pindel, varscan2
- TSHZ3 | c.2419C>A p.L807I | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- TSPAN12 | c.527G>T p.W176L | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT tolerated (0.65); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TTC12 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 173/365 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TTN | c.41579C>A p.A13860E (on ENST00000591111; = p.A6436E on NM_003319.4) | Missense Mutation (SNP) | VAF 115/219 reads (53%) | PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- TYR | c.1070C>A p.A357D | Missense Mutation (SNP) | VAF 72/189 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, varscan2
- U2AF1L4 | c.579-2A>T p.X193_splice (on ENST00000412391; = p.X135_splice on NM_144987.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 29/101 reads (29%) | called by muse, mutect2, varscan2
- UBE2NL | c.328C>G p.Q110E | Missense Mutation (SNP) | VAF 194/208 reads (93%) | SIFT deleterious (0.01); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- UNC45B | c.1272G>T p.E424D | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- USP32 | c.3507G>T p.W1169C | Missense Mutation (SNP) | VAF 84/235 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- USP33 | c.2111A>T p.N704I | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- UTP20 | c.7111A>G p.T2371A | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VCAN | c.5378T>C p.F1793S | Missense Mutation (SNP) | VAF 84/207 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- VCAN | c.9887G>A p.C3296Y | Missense Mutation (SNP) | VAF 136/308 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- WDR11 | c.1756G>T p.V586L | Missense Mutation (SNP) | VAF 76/167 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- WSB1 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 211/351 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- XIRP2 | c.103G>T p.V35L (on ENST00000628543; = p.V210L on NM_152381.6) | Missense Mutation (SNP) | VAF 80/246 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, varscan2
- ZEB2 | c.2723C>A p.T908N | Missense Mutation (SNP) | VAF 151/319 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- ZNF133 | c.1576G>T p.E526* (on ENST00000316358 / NM_001352454.2; = p.E525* on NM_003434.7 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 51/145 reads (35%) | called by muse, mutect2, varscan2
- ZNF141 | c.4-1G>A p.X2_splice | Splice Site (SNP) | VAF 25/78 reads (32%) | called by muse, mutect2, varscan2
- ZNF208 | c.1852T>C p.F618L | Missense Mutation (SNP) | VAF 109/236 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZNF527 | c.645G>T p.E215D | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF536 | c.1383G>T p.K461N | Missense Mutation (SNP) | VAF 83/135 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF804A | c.258G>T p.R86S | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZSCAN5B | c.1079G>T p.C360F | Missense Mutation (SNP) | VAF 136/294 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ACAN | c.693G>A p.R231= | Silent (SNP) | VAF 74/168 reads (44%) | called by muse, mutect2, varscan2
- ADGRL2 | c.3909A>T p.A1303= (on ENST00000370717 / NM_001366005.1; = p.A1247= on NM_012302.4) | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as rs755479076; called by muse, mutect2, varscan2
- ADGRV1 | c.10011T>G p.L3337= | Silent (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- ANKRD24 | c.2931C>T p.N977= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs1019103263; called by muse, varscan2
- AQP12A | c.21C>T p.S7= | Silent (SNP) | VAF 40/101 reads (40%) | catalogued as rs778744874, COSV61837346; called by muse, mutect2, varscan2
- ARFGEF3 | c.996G>T p.L332= | Silent (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2
- ASB13 | c.654G>A p.P218= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs149225019; called by muse, mutect2, varscan2
- AVPR1A | c.492G>A p.A164= | Silent (SNP) | VAF 60/170 reads (35%) | catalogued as rs945631623, COSV54546440; called by muse, mutect2, varscan2
- CACNG6 | c.489C>A p.L163= | Silent (SNP) | VAF 234/664 reads (35%) | called by muse, mutect2, varscan2
- CCDC80 | c.2697G>T p.R899= | Silent (SNP) | VAF 62/139 reads (45%) | called by muse, mutect2, varscan2
- CDHR2 | c.183G>C p.G61= | Silent (SNP) | VAF 33/83 reads (40%) | catalogued as COSV56138008; called by muse, mutect2, varscan2
- CDHR3 | c.1395C>T p.S465= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as rs1367824365, COSV58421173; called by muse, mutect2, varscan2
- CLIP2 | c.708G>T p.R236= | Silent (SNP) | VAF 173/503 reads (34%) | called by muse, mutect2, varscan2
- COL22A1 | c.4146C>T p.V1382= | Silent (SNP) | VAF 41/126 reads (33%) | catalogued as rs980514669; called by muse, mutect2, varscan2
- COL4A4 | c.108A>G p.V36= | Silent (SNP) | VAF 44/92 reads (48%) | catalogued as COSV100307373; called by muse, mutect2, varscan2
- COMMD1 | c.360G>T p.R120= | Silent (SNP) | VAF 44/92 reads (48%) | called by muse, varscan2
- CPPED1 | c.345G>T p.V115= | Silent (SNP) | VAF 54/70 reads (77%) | called by muse, mutect2, varscan2
- CSMD1 | c.3318A>T p.G1106= (on ENST00000520002; = p.G1105= on NM_033225.6) | Silent (SNP) | VAF 22/46 reads (48%) | called by muse, mutect2, varscan2
- CSMD3 | c.5400G>T p.V1800= (on ENST00000297405 / NM_001363185.1; = p.V1696= on NM_052900.3) | Silent (SNP) | VAF 112/227 reads (49%) | called by muse, mutect2, varscan2
- CYFIP2 | c.2926C>T p.L976= (on ENST00000616178 / NM_001291722.2; = p.L951= on NM_014376.4) | Silent (SNP) | VAF 81/193 reads (42%) | called by muse, mutect2, varscan2
- DDX54 | c.1521C>T p.G507= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as rs1348504753; called by muse, mutect2, varscan2
- DMBX1 | c.51C>T p.L17= | Silent (SNP) | VAF 67/182 reads (37%) | called by muse, mutect2, varscan2
- DYNC1I1 | c.1236T>C p.D412= | Silent (SNP) | VAF 132/289 reads (46%) | called by muse, mutect2, varscan2
- EFHC2 | c.732A>G p.G244= | Silent (SNP) | VAF 25/27 reads (93%) | called by muse, mutect2, varscan2
- EIF2D | c.1611C>A p.A537= | Silent (SNP) | VAF 91/190 reads (48%) | called by muse, mutect2, varscan2
- EPHA3 | c.2524C>A p.R842= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as COSV60707193; called by muse, mutect2, varscan2
- ERN1 | c.1395C>T p.P465= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as rs375031481; called by muse, mutect2, varscan2
- ESS2 | c.48G>T p.A16= | Silent (SNP) | VAF 12/15 reads (80%) | catalogued as rs746229513; called by muse, mutect2, varscan2
- EYS | c.501G>T p.V167= | Silent (SNP) | VAF 65/143 reads (45%) | catalogued as COSV60982923; called by muse, mutect2, varscan2
- FGL2 | c.216C>T p.F72= | Silent (SNP) | VAF 165/370 reads (45%) | called by muse, mutect2, varscan2
- FIBCD1 | c.984C>A p.A328= | Silent (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- FNDC7 | c.903C>T p.G301= | Silent (SNP) | VAF 97/224 reads (43%) | catalogued as rs764076233; called by muse, mutect2, varscan2
- FZD2 | c.969G>A p.K323= | Silent (SNP) | VAF 32/103 reads (31%) | catalogued as COSV100190486; called by muse, mutect2, varscan2
- GOLGA6B | c.624G>T p.R208= | Silent (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- GPA33 | c.378G>A p.E126= | Silent (SNP) | VAF 48/115 reads (42%) | catalogued as COSV63300547; called by muse, mutect2, varscan2
- GPR148 | c.774G>T p.R258= | Silent (SNP) | VAF 96/301 reads (32%) | catalogued as COSV59307745; called by muse, mutect2, varscan2
- GRM8 | c.2412A>T p.T804= | Silent (SNP) | VAF 76/167 reads (46%) | called by muse, mutect2, varscan2
- GSAP | c.1209C>G p.L403= | Silent (SNP) | VAF 106/288 reads (37%) | called by muse, mutect2, varscan2
- H2BU1 | c.366C>T p.Y122= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs755877874; called by muse, mutect2, varscan2
- HIVEP2 | c.2904C>T p.S968= | Silent (SNP) | VAF 66/134 reads (49%) | called by muse, mutect2, varscan2
- HSPA6 | c.1539C>T p.S513= | Silent (SNP) | VAF 21/64 reads (33%) | called by muse, mutect2, varscan2
- IGF2BP1 | c.408C>T p.I136= | Silent (SNP) | VAF 128/336 reads (38%) | catalogued as COSV51731334; called by muse, varscan2
- IGHV4-31 | c.333G>T p.T111= | Silent (SNP) | VAF 52/564 reads (9%) | called by muse, mutect2
- INHBC | c.237C>T p.L79= | Silent (SNP) | VAF 43/124 reads (35%) | catalogued as COSV100548068; called by muse, mutect2, varscan2
- IQGAP2 | c.3723G>T p.L1241= | Silent (SNP) | VAF 108/324 reads (33%) | catalogued as rs1465296421; called by muse, varscan2
- JAK3 | c.2089C>A p.R697= | Silent (SNP) | VAF 130/303 reads (43%) | called by muse, mutect2, varscan2
- KIF1B | c.1098C>T p.A366= (on ENST00000377086 / NM_001365952.1; = p.A360= on NM_015074.3) | Silent (SNP) | VAF 48/183 reads (26%) | catalogued as rs1256105670; called by muse, mutect2, varscan2
- KLHL1 | c.1995G>T p.R665= | Silent (SNP) | VAF 191/341 reads (56%) | called by muse, mutect2, varscan2
- KRTAP21-1 | c.132C>A p.S44= | Silent (SNP) | VAF 94/303 reads (31%) | catalogued as COSV100624905, COSV58646304; called by muse, mutect2, varscan2
- LARGE2 | c.534C>G p.L178= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs370021898; called by muse, mutect2, varscan2
- LDLR | c.279G>A p.V93= | Silent (SNP) | VAF 104/229 reads (45%) | called by muse, mutect2, varscan2
- LEFTY1 | c.201C>T p.R67= | Silent (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- LNPEP | c.732C>T p.A244= | Silent (SNP) | VAF 81/190 reads (43%) | called by muse, mutect2, varscan2
- MADD | c.3552A>T p.P1184= | Silent (SNP) | VAF 41/131 reads (31%) | catalogued as rs143711042; called by muse, mutect2, varscan2
- MAGEB10 | c.237C>T p.H79= | Silent (SNP) | VAF 16/16 reads (100%) | catalogued as rs1363847270; called by muse, mutect2, varscan2
- MAGEL2 | c.2925C>A p.T975= | Silent (SNP) | VAF 17/27 reads (63%) | catalogued as COSV58566675; called by muse, mutect2, varscan2
- MAP3K5 | c.2652G>T p.L884= | Silent (SNP) | VAF 103/280 reads (37%) | called by muse, mutect2, varscan2
- MAP3K8 | c.966G>A p.T322= | Silent (SNP) | VAF 53/113 reads (47%) | catalogued as rs1257371069, COSV99551870; called by muse, mutect2, varscan2
- MEDAG | c.6G>T p.A2= | Silent (SNP) | VAF 13/20 reads (65%) | called by muse, mutect2, varscan2
- MOCS1 | c.480G>T p.L160= | Silent (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2, varscan2
- MUC7 | c.318G>T p.V106= | Silent (SNP) | VAF 88/209 reads (42%) | called by muse, mutect2, varscan2
- MYLK2 | c.135G>C p.P45= | Silent (SNP) | VAF 36/58 reads (62%) | called by muse, mutect2, varscan2
- MYO16 | c.5247C>A p.S1749= | Silent (SNP) | VAF 16/59 reads (27%) | called by muse, mutect2, varscan2
- MYO1F | c.1780C>A p.R594= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV100596326, COSV100596670; called by muse, mutect2, varscan2
- NCKAP1L | c.2817C>A p.P939= | Silent (SNP) | VAF 114/208 reads (55%) | catalogued as COSV53207754; called by muse, mutect2, varscan2
- NLRP5 | c.3384C>T p.N1128= | Silent (SNP) | VAF 45/93 reads (48%) | called by muse, mutect2, varscan2
- NRG2 | c.1452C>A p.V484= | Silent (SNP) | VAF 79/209 reads (38%) | called by muse, mutect2, varscan2
- NTRK3 | c.1557G>A p.Q519= | Silent (SNP) | VAF 53/131 reads (40%) | catalogued as COSV58114692; called by muse, mutect2, varscan2
- NWD1 | c.1827G>T p.L609= | Silent (SNP) | VAF 92/237 reads (39%) | called by muse, mutect2, varscan2
- OR2M5 | c.729T>C p.S243= | Silent (SNP) | VAF 246/562 reads (44%) | called by muse, mutect2, varscan2
- PCARE | c.2145C>A p.A715= | Silent (SNP) | VAF 85/155 reads (55%) | called by muse, mutect2, varscan2
- PCDH11X | c.1401C>A p.T467= | Silent (SNP) | VAF 82/105 reads (78%) | called by muse, mutect2, varscan2
- PDZRN4 | c.1620C>T p.D540= (on ENST00000402685 / NM_001164595.2; = p.D282= on NM_013377.4) | Silent (SNP) | VAF 126/196 reads (64%) | called by muse, mutect2, varscan2
- PLEC | c.9237G>T p.L3079= (on ENST00000322810 / NM_201380.4; = p.L2969= on NM_000445.5) | Silent (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2
- PMM1 | c.510G>A p.L170= | Silent (SNP) | VAF 9/11 reads (82%) | called by muse, mutect2, varscan2
- PRX | c.1878C>A p.V626= | Silent (SNP) | VAF 289/676 reads (43%) | called by muse, mutect2, varscan2
- PSG11 | c.867T>A p.P289= | Silent (SNP) | VAF 103/392 reads (26%) | catalogued as COSV60458082; called by muse, mutect2
- RAPGEF4 | c.1419T>C p.D473= | Silent (SNP) | VAF 28/73 reads (38%) | called by muse, mutect2, varscan2
- RIT2 | c.183C>G p.V61= | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as rs772207386; called by muse, mutect2, varscan2
- RSAD2 | c.951G>T p.R317= | Silent (SNP) | VAF 49/144 reads (34%) | called by muse, mutect2, varscan2
- RSPH6A | c.174A>T p.S58= | Silent (SNP) | VAF 32/78 reads (41%) | called by muse, mutect2, varscan2
- SARDH | c.1434G>T p.L478= | Silent (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- SART1 | c.1953G>T p.L651= | Silent (SNP) | VAF 20/74 reads (27%) | called by muse, mutect2, varscan2
- SART3 | c.156G>T p.G52= | Silent (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2, varscan2
- SCN5A | c.2952C>A p.L984= | Silent (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- SELE | c.1026G>A p.Q342= | Silent (SNP) | VAF 70/118 reads (59%) | called by muse, mutect2, varscan2
- SETBP1 | c.693C>A p.V231= | Silent (SNP) | VAF 126/265 reads (48%) | called by muse, mutect2
- SLC25A28 | c.942G>T p.T314= | Silent (SNP) | VAF 52/155 reads (34%) | called by muse, mutect2, varscan2
- SLC45A4 | c.1224G>T p.T408= (on ENST00000517878 / NM_001286646.2; = p.T357= on NM_001080431.2) | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV50173436; called by muse, mutect2, varscan2
- SLC8A2 | c.2040G>C p.T680= | Silent (SNP) | VAF 89/207 reads (43%) | called by muse, mutect2, varscan2
- SPATA31A1 | c.303G>T p.L101= | Silent (SNP) | VAF 71/180 reads (39%) | catalogued as rs1173579728; called by muse, mutect2, varscan2
- SPTBN4 | c.378G>T p.A126= | Silent (SNP) | VAF 58/148 reads (39%) | called by muse, varscan2
- STOX2 | c.2715G>T p.P905= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV57851458; called by muse, mutect2, varscan2
- STYXL2 | c.2466C>T p.P822= | Silent (SNP) | VAF 56/172 reads (33%) | catalogued as COSV54808211; called by muse, mutect2, varscan2
- SUN3 | c.477C>T p.D159= | Silent (SNP) | VAF 49/125 reads (39%) | called by muse, mutect2, varscan2
- TEK | c.1725T>C p.Y575= | Silent (SNP) | VAF 136/269 reads (51%) | called by muse, mutect2, varscan2
- TENM1 | c.1407C>A p.V469= | Silent (SNP) | VAF 98/107 reads (92%) | called by muse, mutect2, varscan2
- TLE3 | c.2307G>A p.E769= | Silent (SNP) | VAF 71/188 reads (38%) | called by muse, mutect2, varscan2
- TLL1 | c.2076C>T p.F692= | Silent (SNP) | VAF 70/176 reads (40%) | catalogued as rs777649235, COSV50277821, COSV50331009; called by muse, mutect2, varscan2
- TMEM132D | c.2346G>T p.R782= | Silent (SNP) | VAF 234/428 reads (55%) | catalogued as COSV67159334; called by muse, mutect2, varscan2
- TP53 | c.750C>T p.P250= | Silent (SNP) | VAF 202/236 reads (86%) | catalogued as COSV52876092; called by muse, varscan2
- TPPP2 | c.93C>A p.S31= | Silent (SNP) | VAF 50/108 reads (46%) | catalogued as COSV53875043; called by muse, mutect2, varscan2
- TREML4 | c.486C>A p.S162= | Silent (SNP) | VAF 63/177 reads (36%) | called by muse, mutect2, varscan2
- TRPA1 | c.2853C>A p.V951= | Silent (SNP) | VAF 46/135 reads (34%) | called by muse, mutect2, varscan2
- TRPC4 | c.426C>T p.D142= | Silent (SNP) | VAF 180/242 reads (74%) | called by muse, varscan2
- TRRAP | c.6381G>T p.V2127= (on ENST00000359863 / NM_001244580.1; = p.V2109= on NM_003496.3) | Silent (SNP) | VAF 15/150 reads (10%) | called by muse, mutect2, varscan2
- TTC21A | c.1095G>A p.K365= | Silent (SNP) | VAF 39/100 reads (39%) | called by muse, mutect2, varscan2
- UNC5C | c.480G>A p.V160= | Silent (SNP) | VAF 52/187 reads (28%) | catalogued as rs139673541; called by muse, mutect2, varscan2
- USP5 | c.408G>T p.L136= | Silent (SNP) | VAF 95/113 reads (84%) | catalogued as rs1555128184; called by muse, mutect2, varscan2
- VPS13D | c.348C>T p.A116= | Silent (SNP) | VAF 83/196 reads (42%) | catalogued as rs747953454; called by muse, mutect2, varscan2
- WDR55 | c.873C>G p.G291= | Silent (SNP) | VAF 12/72 reads (17%) | called by muse, mutect2, varscan2
- ZNF354C | c.279A>G p.A93= | Silent (SNP) | VAF 61/120 reads (51%) | catalogued as rs979280998; called by muse, mutect2, varscan2
- ZNF425 | c.1287G>A p.L429= | Silent (SNP) | VAF 100/198 reads (51%) | called by muse, mutect2, varscan2
- ZNF98 | c.654C>A p.A218= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV100757332; called by mutect2, varscan2
- CAMSAP3 | c.621+214G>T | Intron (SNP) | VAF 13/19 reads (68%) | called by muse, mutect2, varscan2
- CCNQP1 | n.2T>C | RNA (SNP) | VAF 51/141 reads (36%) | catalogued as rs374881950; called by muse, mutect2, varscan2
- IL19 | c.-83C>G | 5'UTR (SNP) | VAF 33/74 reads (45%) | called by muse, mutect2, varscan2
- MIR1208 | n.13C>G | RNA (SNP) | VAF 57/147 reads (39%) | called by muse, mutect2, varscan2
- MIR7-3 | n.84G>A | RNA (SNP) | VAF 231/566 reads (41%) | catalogued as rs1015364500; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99791839 T>A | 3'Flank (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- SNORD116-28 | n.52T>C | RNA (SNP) | VAF 113/230 reads (49%) | called by muse, mutect2, varscan2
- TRAC | c.*321C>A | 3'UTR (SNP) | VAF 123/263 reads (47%) | called by muse, mutect2, varscan2
